Gene-level copy-number profile of tumor specimen TCGA-GJ-A3OU-01A from TCGA case TCGA-GJ-A3OU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.3 years (21,671 days).
Specimen TCGA-GJ-A3OU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.1328977f-fe65-40b6-bbc6-8c471d9b329c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GJ-A3OU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/856dee93-71dc-4e2c-944f-9f5b4e2429b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,040; copy number 2: 43,020; copy number 3: 2,815; copy number 4: 166; copy number 5: 18; copy number 6: 5; copy number 7: 1,726; copy number 8: 5; copy number 9: 19; copy number 14: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GJ-A3OU-01A-31D-A381-01): tumor purity 0.28, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,779 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:236,981,339–238,108,567, 18 genes, copy number 5: RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9.
- chr8:150,584–4,994,972, 64 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr8:6,924,697–12,818,291, 264 genes, copy number 7 (broad region; genes not listed).
- chr8:53,388,701–145,066,685, 1,433 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
